Somatic mutation profile of tumor specimen TCGA-17-Z030-01A (aliquot TCGA-17-Z030-01A-01W-0746-08) from TCGA case TCGA-17-Z030, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a79e84d-2632-43b4-83a2-d54794114f33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z030-11A (Solid Tissue Normal), aliquot TCGA-17-Z030-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fafcbcec-5c8a-4c70-af23-2e76a745a08c

The open-access MAF lists 586 somatic variants for this specimen: 450 protein-altering or splice-affecting, 124 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 124, Nonsense Mutation 43, Splice Site 18, Frame Shift Del 13, Intron 6, RNA 4, Frame Shift Ins 3, Splice Region 2, Translation Start Site 2, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AASS | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs769756628; called by muse, mutect2, varscan2
- ACSM2A | c.314G>T p.R105L (on ENST00000219054; = p.R26L on NM_001308169.2) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs371291843; called by muse, mutect2, varscan2
- ADAM19 | c.2527G>T p.A843S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.665); catalogued as rs199716249, COSV57426292; called by mutect2, varscan2
- ADAMTS19 | c.2049C>A p.Y683* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV50777169; called by muse, mutect2, varscan2
- ADAMTS20 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745547876; called by muse, varscan2
- ADGRL4 | c.1179C>G p.Y393* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs777216650, COSV100875978; called by muse, mutect2, varscan2
- AKNAD1 | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1161841827; called by muse, mutect2, varscan2
- AL035460.1 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV63028108; called by muse, mutect2, varscan2
- ALX1 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.843); catalogued as rs1259147934, COSV57493559; called by muse, mutect2
- AMPD1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.392); catalogued as COSV62418903; called by muse, mutect2, varscan2
- ANKRD17 | c.4654G>T p.A1552S | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.098); catalogued as COSV58227528; called by muse, mutect2
- AOC1 | c.2019C>A p.F673L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs1245640200; called by muse, mutect2, varscan2
- APOB | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV104373561, COSV51950894; called by muse, mutect2
- ARHGEF37 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs765561493; called by muse, mutect2, varscan2
- ARMC8 | c.531G>T p.G177= (on ENST00000469044 / NM_001363941.2; = p.G163= on NM_014154.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 5/43 reads (12%) | catalogued as rs957793427, COSV61767598; called by muse, mutect2, varscan2
- ARPP21 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1446735934; called by muse, mutect2, varscan2
- BMPR1B | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427765668; called by muse, mutect2, varscan2
- CACNA2D1 | c.1806A>T p.K602N (on ENST00000356253 / NM_001366867.1; = p.K583N on NM_000722.4) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as COSV100666002; called by muse, mutect2, varscan2
- CAMTA1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57895963; called by muse, varscan2
- CAPSL | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV68438270; called by muse, mutect2, varscan2
- CASP5 | c.1096+1G>A p.X366_splice | Splice Site (SNP) | VAF 28/252 reads (11%) | catalogued as rs141481245; called by muse, mutect2, varscan2
- CDH18 | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs368650801, COSV56955125; called by muse, mutect2, varscan2
- CDH18 | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1367718572; called by muse, mutect2, varscan2
- CHMP4C | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as rs375563916; called by muse, mutect2, varscan2
- CHMP4C | c.483+1G>T p.X161_splice | Splice Site (SNP) | VAF 10/78 reads (13%) | catalogued as rs1192015768; called by muse, mutect2, varscan2
- CLCA4 | c.557+1G>T p.X186_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as rs1305228229, COSV55368481; called by muse, mutect2, varscan2
- CLDN25 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs35111413; called by muse, mutect2, varscan2
- CLIC6 | c.1665-1G>T p.X555_splice (on ENST00000360731 / NM_001317009.2; = p.X537_splice on NM_053277.3) | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV62449557; called by muse, mutect2
- CNTN1 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61645631; called by muse, mutect2, varscan2
- COL21A1 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs1285342779, COSV55174091; called by muse, mutect2, varscan2
- COL6A6 | c.4382G>T p.G1461V | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62027444; called by muse, varscan2
- CPN1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs767463959; called by muse, mutect2
- CRACR2A | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as rs1392013710, COSV99068794; called by muse, mutect2
- CSTL1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/105 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs760903708; called by muse, mutect2, varscan2
- DCAF6 | c.1843A>G p.S615G (on ENST00000312263 / NM_001349778.1; = p.S635G on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.159); catalogued as rs750158437; called by muse, mutect2, varscan2
- DCAF8L1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV71595538; called by muse, mutect2, varscan2
- DEUP1 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs267603249; called by muse, mutect2, varscan2
- DHX58 | c.1590G>T p.L530F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1555662020; called by muse, mutect2, varscan2
- DMRT3 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51907299; called by muse, mutect2, varscan2
- DNAH11 | c.11156T>C p.I3719T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs1359561659; called by muse, mutect2, varscan2
- DPF1 | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV62792375; called by muse, mutect2, varscan2
- DRC1 | c.1397-2A>T p.X466_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as rs752882432; called by muse, mutect2, varscan2
- DSC3 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753599724; called by muse, mutect2, varscan2
- EHD3 | c.969del p.K324Rfs*33 | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | catalogued as COSV100434945; called by mutect2, varscan2
- EPHB3 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs757806643; called by mutect2, varscan2
- EXT2 | c.1991C>T p.S664L (on ENST00000343631; = p.S697L on NM_000401.3) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100640643; called by muse, mutect2, varscan2
- FASTKD3 | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.184); catalogued as rs781701498; called by muse, mutect2, varscan2
- FAT4 | c.8252G>T p.G2751V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767230275, COSV58686478; called by muse, mutect2, varscan2
- FGF13 | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59551454; called by muse, mutect2, varscan2
- FLG | c.7306G>A p.G2436R | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs770098980; called by muse, mutect2, varscan2
- FRYL | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466416251; called by muse, mutect2, varscan2
- FSTL5 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60183621; called by muse, mutect2, varscan2
- GABRB3 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV54648717, COSV54671867; called by muse, mutect2, varscan2
- GABRR2 | c.767C>A p.T256K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.71); PolyPhen probably damaging (1); catalogued as COSV68765816; called by mutect2, varscan2
- GBA3 | c.398G>C p.W133S | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289461251; called by muse, mutect2, varscan2
- GDAP1 | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM032929; called by muse, varscan2
- GFRAL | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV99080215; called by muse, mutect2, varscan2
- GP1BA | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 69/372 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.5); catalogued as rs1438163121; called by muse, mutect2, varscan2
- GPAT2 | c.1171G>C p.A391P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.491); catalogued as rs745642470; called by muse, mutect2, varscan2
- GPR142 | c.140A>T p.H47L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV59519034; called by muse, mutect2, varscan2
- GRIK1 | c.1634C>A p.S545Y | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1481677993, COSV100517408, COSV58711152; called by muse, varscan2
- GRIK5 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV53475430; called by muse, mutect2
- GRIN2B | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs772078838, COSV74204997; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- HAS1 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 35/196 reads (18%) | catalogued as rs1163829559; called by muse, mutect2, varscan2
- HDAC9 | c.1835C>A p.S612Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV67781752; called by muse, mutect2
- HERC2 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1312200357; called by muse, mutect2, varscan2
- HGF | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV55946382; called by muse, mutect2, varscan2
- HNRNPU | c.730G>A p.A244T (on ENST00000283179; = p.A306T on NM_004501.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762846113; called by muse, mutect2, varscan2
- IFT172 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53133141; called by muse, mutect2
- IGDCC3 | c.1991G>T p.R664M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100031573; called by muse, mutect2
- IGF2BP2 | c.1138G>T p.V380L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV60482375; called by mutect2, varscan2
- IGSF9B | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100317866; called by muse, mutect2, varscan2
- INPP4B | c.1574G>T p.W525L | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1217385988; called by muse, mutect2, varscan2
- ITGA10 | c.3088G>T p.E1030* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100994756, COSV65196330; called by muse, mutect2, varscan2
- IWS1 | c.1756A>G p.K586E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV54866735; called by muse, mutect2, varscan2
- KCNT2 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs773215569, COSV54081524, COSV54096331; called by muse, mutect2, varscan2
- KEAP1 | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99407169; called by muse, mutect2, varscan2
- KEL | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.372); catalogued as COSV62337047; called by muse, mutect2, varscan2
- KLF7 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV58743612; called by muse, mutect2, varscan2
- KMT2C | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100077150; called by muse, mutect2, varscan2
- LAD1 | c.1248G>T p.R416= | Splice Region (SNP) | VAF 57/228 reads (25%) | catalogued as rs1208179655; called by muse, mutect2, varscan2
- LRP1B | c.8356G>T p.D2786Y | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67197473; called by muse, mutect2
- LRP1B | c.6396G>T p.E2132D | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101260528; called by muse, mutect2
- LRRC7 | c.169G>T p.G57C (on ENST00000651989 / NM_001370785.2; = p.G24C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50496505; called by muse, varscan2
- LRRTM4 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1382799878; called by muse, mutect2, varscan2
- LRRTM4 | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101297775, COSV69143045; called by muse, mutect2, varscan2
- LRTM2 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs1230726348, COSV54565323; called by muse, mutect2, varscan2
- MAGEE2 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100973230; called by muse, mutect2
- MLH3 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1409969294, COSV53135749; called by muse, mutect2, varscan2
- MUC16 | c.12835C>G p.H4279D | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as COSV67471757; called by muse, mutect2, varscan2
- NDUFV1 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.906); catalogued as rs1453596973; called by muse, mutect2, varscan2
- NEB | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); catalogued as COSV99420003; called by muse, mutect2
- NEFH | c.2842_2844del p.K948del | In Frame Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs753511635; called by pindel, varscan2
- NELL2 | c.859T>A p.W287R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV61571093; called by muse, mutect2, varscan2
- NHLRC2 | c.2074G>C p.D692H | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100992985; called by muse, mutect2
- NLRP5 | c.2769C>A p.C923* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as COSV66763243; called by muse, mutect2, varscan2
- NLRP8 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs149738419; called by mutect2, varscan2
- NOMO1 | c.2413G>A p.G805S | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778566291; called by muse, mutect2, varscan2
- NPAS2 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1443198927; called by muse, mutect2, varscan2
- NPBWR1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1465331883; called by muse, mutect2, varscan2
- OR1C1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1471871643; called by muse, mutect2, varscan2
- OR2S2 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59530882; called by muse, mutect2, varscan2
- OR4C15 | c.1014G>T p.L338F (on ENST00000314644; = p.L284F on NM_001001920.2) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.222); catalogued as COSV58952497, COSV58952781; called by muse, mutect2
- OR4K15 | c.320C>T p.A107V (on ENST00000305051; = p.A83V on NM_001005486.1) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1388904156; called by muse, mutect2, varscan2
- OR5R1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.633); catalogued as COSV56573114; called by muse, mutect2, varscan2
- OR6N1 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 138/831 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1176003570; called by muse, mutect2
- OR7G1 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV53316905; called by muse, mutect2, varscan2
- OSMR | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99952916; called by muse, mutect2
- OTOGL | c.6595G>T p.G2199* (on ENST00000547103; = p.G2190* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs1195666689, COSV54016058; called by muse, mutect2, varscan2
- OTUD6B | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99576046; called by muse, mutect2, varscan2
- PCDH11X | c.1646C>A p.P549H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV53457013; called by muse, mutect2, varscan2
- PCDH18 | c.1171C>A p.L391M | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.841); catalogued as COSV61271929; called by muse, mutect2
- PCDHB1 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60631507; called by muse, mutect2, varscan2
- PGBD5 | c.868+1G>A p.X290_splice (on ENST00000525115; = p.X359_splice on NM_001258311.2) | Splice Site (SNP) | VAF 17/116 reads (15%) | catalogued as rs772875176; called by muse, mutect2, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 15/117 reads (13%) | catalogued as rs755454854; called by mutect2, pindel
- PKD1L1 | c.3143C>T p.S1048F | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.765); catalogued as rs1323818746, COSV56962315; called by muse, mutect2, varscan2
- PKD1L2 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as rs370282671; called by muse, mutect2, varscan2
- PLXND1 | c.4141C>T p.Q1381* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100139582; called by muse, mutect2, varscan2
- PPFIA2 | c.484del p.Q162Sfs*16 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | catalogued as COSV61037577; called by mutect2, pindel, varscan2
- PRDM9 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV57001907; called by muse, mutect2, varscan2
- PRKD1 | c.2397G>T p.M799I | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100121714; called by muse, mutect2
- PRKD1 | c.738G>T p.R246S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV59560939; called by muse, mutect2
- PSG1 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 104/733 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs191320644; called by muse, mutect2, varscan2
- PSG7 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV68444437; called by muse, mutect2, varscan2
- PTCHD4 | c.1969G>T p.V657F | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs1400803345; called by muse, mutect2, varscan2
- PTPRS | c.5756G>T p.R1919L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53634020; called by muse, mutect2, varscan2
- PWWP3B | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV100530826; called by muse, mutect2, varscan2
- RCBTB2 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV60651232; called by muse, mutect2, varscan2
- RP1L1 | c.4199C>A p.P1400Q | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs769518612; called by muse, varscan2
- RTKN | c.1300C>T p.P434S (on ENST00000272430 / NM_001015055.2; = p.P421S on NM_033046.2) | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); catalogued as COSV99269334; called by muse, mutect2, varscan2
- RUNX1T1 | c.1282G>T p.A428S (on ENST00000265814 / NM_001198628.1; = p.A401S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV56153400; called by muse, mutect2, varscan2
- RYR2 | c.10564C>A p.P3522T | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV63667814; called by muse, varscan2
- SCIN | c.2125G>T p.G709C (on ENST00000297029 / NM_001112706.3; = p.G462C on NM_033128.3) | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1380420274; called by muse, mutect2, varscan2
- SDK1 | c.4655G>T p.R1552L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67390127; called by muse, mutect2, varscan2
- SELE | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV60976870; called by muse, mutect2, varscan2
- SLAMF1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as rs1011466683, COSV52497735; called by muse, mutect2
- SLC17A2 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); catalogued as COSV99614973; called by muse, mutect2, varscan2
- SLC2A3 | c.1341C>A p.F447L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1396668769; called by muse, mutect2, varscan2
- SLC40A1 | c.1305del p.S436Lfs*17 | Frame Shift Del (DEL) | VAF 13/129 reads (10%) | catalogued as COSV53724235; called by mutect2, pindel
- SLC4A10 | c.1103C>A p.T368N (on ENST00000446997 / NM_001354461.2; = p.T338N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1039822470, COSV99763035; called by muse, mutect2, varscan2
- SLC4A5 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV61024831; called by muse, mutect2, varscan2
- SLC5A8 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs932973196; called by muse, mutect2, varscan2
- SLC8A3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375603290; called by muse, varscan2
- SLC8A3 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV63526605; called by muse, varscan2
- SMYD3 | c.950C>T p.S317F (on ENST00000490107 / NM_001375962.1; = p.S258F on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as COSV63626425; called by muse, mutect2
- SOGA1 | c.3560G>T p.R1187L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs369369459, COSV99415686; called by muse, mutect2, varscan2
- STC1 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV99282602; called by muse, mutect2
- TAS2R50 | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV67852967; called by muse, mutect2, varscan2
- TG | c.6102G>A p.M2034I | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55074951; called by muse, mutect2, varscan2
- THPO | c.828G>T p.Q276H (on ENST00000649095 / NM_001290003.1; = p.Q136H on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as rs1371274994; called by muse, mutect2, varscan2
- TMEM132D | c.2464G>T p.V822F | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV67161234; called by muse, mutect2, varscan2
- TMEM132E | c.591G>T p.E197D (on ENST00000321639; = p.E287D on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1371889902; called by mutect2, varscan2
- TRAK1 | c.1816G>T p.G606C (on ENST00000327628 / NM_001349247.2; = p.G548C on NM_014965.5) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58259585; called by muse, mutect2, varscan2
- TRIM58 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs749714512; called by muse, varscan2
- TRPV6 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as rs1239521590; called by muse, mutect2, varscan2
- TSHZ3 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1568367246, COSV53662974; called by muse, mutect2, varscan2
- TTBK1 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV52488297; called by muse, mutect2, varscan2
- UACA | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760320320, COSV59854891; called by muse, mutect2, varscan2
- UCHL1 | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV99449148; called by muse, mutect2
- UPK1B | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs1351904366; called by muse, mutect2, varscan2
- USH2A | c.3527C>T p.S1176F | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100236705, COSV56389994; called by muse, mutect2
- WT1 | c.1304-1G>T p.X435_splice | Splice Site (SNP) | VAF 27/177 reads (15%) | catalogued as COSV60066475, COSV60069859; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.117); catalogued as rs772572650, COSV60873636; called by muse, mutect2, varscan2
- ZMYM6 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs761003098; called by muse, mutect2, varscan2
- ZNF251 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs757533001, COSV52957046, COSV99478644; called by muse, mutect2, varscan2
- ZNF330 | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53708339; called by muse, mutect2, varscan2
- ZNF347 | c.2162G>T p.R721L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs150489253, COSV100498380; called by muse, mutect2, varscan2
- ZNF831 | c.1956T>A p.S652R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs763107171; called by muse, mutect2, varscan2
- AADACL2 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ABCA13 | c.11257G>T p.G3753C | Missense Mutation (SNP) | VAF 169/288 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC5 | c.1667G>T p.R556L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ACKR4 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.053); called by muse, mutect2
- ACSL3 | c.1840G>T p.A614S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- ACSM1 | c.1259T>A p.I420N | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ADAM2 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ADAM29 | c.1498G>T p.D500Y | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ADAMTS18 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.7483G>C p.G2495R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRV1 | c.18625G>T p.V6209L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2
- AHNAK | c.6782C>G p.P2261R | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AIM2 | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- ALMS1 | c.3450G>T p.K1150N | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.222); called by muse, mutect2
- ANK3 | c.7441G>A p.E2481K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- ANKLE2 | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD22 | c.575A>C p.*192Sext*3 | Nonstop Mutation (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- APBB1IP | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APOB | c.7335G>C p.E2445D | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, varscan2
- ARHGAP20 | c.2111C>A p.S704* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- ARID1B | c.5519C>T p.A1840V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARPP21 | c.1767G>T p.Q589H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ARSF | c.1511del p.P504Lfs*16 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ASAP1 | c.1519G>C p.A507P | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ASH1L | c.421-1G>T p.X141_splice | Splice Site (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- ASXL1 | c.3490G>T p.G1164* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- ATP13A3 | c.1643T>A p.L548H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP8A2 | c.1058-1G>T p.X353_splice | Splice Site (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- BARD1 | c.1991G>C p.R664T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- BCAT2 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP10 | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- BMS1 | c.3337G>T p.V1113L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BMT2 | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARD11 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC63 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- CD163L1 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CD1B | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 61/566 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CDH12 | c.947T>A p.L316* | Nonsense Mutation (SNP) | VAF 39/199 reads (20%) | called by muse, mutect2, varscan2
- CEMIP | c.3220A>T p.K1074* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- CGNL1 | c.939del p.L313Ffs*44 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- CNOT11 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- COBL | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 56/82 reads (68%) | called by muse, mutect2, varscan2
- COBL | c.857del p.G286Afs*8 | Frame Shift Del (DEL) | VAF 83/162 reads (51%) | called by mutect2, pindel, varscan2
- COL19A1 | c.1853G>C p.G618A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A1 | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPEB1 | c.1367T>A p.M456K (on ENST00000617958; = p.M391K on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- CPS1 | c.1328A>T p.Y443F | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.1589C>G p.A530G (on ENST00000297405 / NM_001363185.1; = p.A426G on NM_052900.3) | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTTNBP2NL | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP4B1 | c.1172T>A p.V391D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CYP4F12 | c.343+1G>T p.X115_splice | Splice Site (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- DCAF12L2 | c.327G>T p.R109S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- DDX27 | c.1564G>T p.V522L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.524); called by muse, mutect2
- DDX60L | c.2859A>T p.E953D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- DIP2C | c.3748C>T p.L1250F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH7 | c.7216G>T p.E2406* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- DNAI4 | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- DNAI4 | c.15A>T p.K5N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); called by muse, mutect2
- DSE | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- DUSP19 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EFCAB6 | c.4310G>T p.R1437M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIF3A | c.1442A>T p.Q481L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ENOPH1 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ENPP1 | c.944T>A p.L315H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- EPHA7 | c.1604T>C p.L535P | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYA3 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.173); called by muse, mutect2
- F13A1 | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- F13B | c.1166G>T p.C389F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAIM2 | c.776C>A p.A259E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FAM47A | c.1974G>T p.M658I | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAN1 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBLN5 | c.1187A>T p.Q396L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- FCGBP | c.5871G>T p.E1957D | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- FER1L6 | c.4994C>G p.P1665R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FERMT3 | c.1192C>A p.P398T (on ENST00000279227 / NM_178443.3; = p.P394T on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FH | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- FOXD3 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FPR2 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FTMT | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FZD10 | c.425A>T p.D142V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- GABRG3 | c.1333del p.S445Pfs*29 | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | called by pindel, varscan2
- GAR1 | c.641-1G>T p.X214_splice | Splice Site (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- GAS2L3 | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- GJA1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GMEB1 | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- GMPS | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPAT2 | c.1466T>A p.L489Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC4 | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2
- GRIK1 | c.1757G>T p.C586F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, varscan2
- GRM1 | c.2188C>A p.P730T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HDAC9 | c.2524C>T p.L842F | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- HECW1 | c.1036A>T p.I346F | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2
- HMGCS1 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | called by muse, varscan2
- HMGCS1 | c.52G>T p.G18* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- HPS4 | c.1835G>T p.S612I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- HPX | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- IGF2BP1 | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- IGFL2 | c.291G>T p.Q97H (on ENST00000377693 / NM_001135113.2; = p.Q108H on NM_001002915.2) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IGHV3-20 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2
- IGKV1-9 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- IGLV4-3 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- INVS | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- IQCE | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- IRX6 | c.1114A>T p.R372W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ITCH | c.1528dup p.R510Pfs*50 (on ENST00000262650 / NM_001257137.3; = p.R469Pfs*50 on NM_031483.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/118 reads (10%) | called by mutect2, pindel
- ITGAM | c.752A>T p.K251M | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITM2A | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- JHY | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KATNBL1 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KAZN | c.1249C>G p.R417G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KCNAB1 | c.885G>C p.W295C (on ENST00000490337 / NM_172160.3; = p.W284C on NM_003471.3) | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNC2 | c.516dup p.D173Rfs*80 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel
- KCNH1 | c.1730A>T p.K577M (on ENST00000271751 / NM_172362.3; = p.K550M on NM_002238.4) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.375); called by muse, mutect2
- KCNH8 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH8 | c.1920G>T p.Q640H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); called by muse, mutect2
- KCNK5 | c.1176G>T p.M392I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- KCNMB2 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNN3 | c.2015G>T p.G672V (on ENST00000618040 / NM_001204087.1; = p.G657V on NM_002249.6) | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.625); called by muse, mutect2
- KCTD9 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KLB | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2, varscan2
- KNG1 | c.1877A>G p.N626S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2
- KRT72 | c.658A>T p.N220Y | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT75 | c.1133G>T p.R378I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KRTAP19-6 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KRTAP4-5 | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- LAG3 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMA2 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- LCT | c.2550G>T p.K850N | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2
- LCTL | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR6 | c.1481A>T p.Q494L (on ENST00000367278 / NM_001017403.1; = p.Q442L on NM_021636.3) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2
- LIPA | c.1022G>C p.S341T | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.158); called by muse, mutect2
- LMTK2 | c.3412G>T p.E1138* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | called by muse, varscan2
- LSAMP | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LSP1 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- LUM | c.914A>T p.K305M | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MACF1 | c.10764G>T p.Q3588H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- MAGI1 | c.3635-1G>C p.X1212_splice (on ENST00000402939 / NM_001033057.2; = p.X1270_splice on NM_015520.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- MAP1A | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- MCF2L2 | c.2966G>T p.R989I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- MCHR2 | c.76T>A p.Y26N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDGA2 | c.2362C>G p.P788A (on ENST00000399232 / NM_001113498.2; = p.P490A on NM_182830.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MEOX2 | c.820G>C p.G274R | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- MROH7 | c.2399G>C p.W800S | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MS4A6E | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2
- MTCL1 | c.2365G>T p.G789W (on ENST00000306329 / NM_001378206.1; = p.G429W on NM_015210.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MUC16 | c.39476C>A p.P13159H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MUC17 | c.7301C>A p.A2434D | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYCBP2 | c.9409A>G p.I3137V (on ENST00000357337; = p.I3175V on NM_015057.5) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MYH13 | c.5630C>G p.A1877G | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MYH6 | c.3014A>T p.H1005L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- MYO5A | c.3230G>A p.R1077K | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NAALADL2 | c.1597G>T p.G533W | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAV2 | c.3448G>T p.G1150C (on ENST00000396087 / NM_001244963.2; = p.G1127C on NM_145117.5) | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.1819C>G p.Q607E | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NBPF11 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.403); called by mutect2, varscan2
- NCKAP1 | c.2451A>T p.L817F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NDUFA8 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFASC | c.457C>A p.Q153K (on ENST00000339876 / NM_001378329.1; = p.Q147K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2
- NKAIN3 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- NME9 | c.770C>G p.A257G (on ENST00000333911 / NM_001349024.2; = p.A196G on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- NOTCH2 | c.6289A>T p.T2097S | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.057); called by muse, mutect2
- NRXN2 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NTRK2 | c.1633G>A p.G545S (on ENST00000323115 / NM_001369534.1; = p.G561S on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUDT6 | c.671A>C p.Y224S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP98 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NUTM2A | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OGDH | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- OR2L2 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 139/472 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR4D11 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- OR52E6 | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 82/463 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5B3 | c.332A>T p.Y111F | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.011); called by muse, varscan2
- OR5H1 | c.534C>A p.Y178* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- OR6C74 | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6N1 | c.360C>G p.Y120* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- OR8J1 | c.660T>A p.N220K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.597); called by muse, mutect2
- OR8K3 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PAX3 | c.766G>C p.A256P | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PAX5 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAX5 | c.186T>A p.H62Q | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2
- PAX5 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); called by muse, mutect2
- PCARE | c.1509T>A p.C503* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- PCDH11Y | c.3625G>T p.V1209L | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA1 | c.2323G>T p.G775C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDGFRL | c.310A>T p.S104C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PEAK1 | c.4359_4372del p.K1454Rfs*15 | Frame Shift Del (DEL) | VAF 38/300 reads (13%) | called by mutect2, pindel*
- PEAR1 | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PENK | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PHEX | c.1550A>T p.D517V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PHYKPL | c.1085G>A p.G362D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGY | c.130A>T p.S44C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PIP5K1B | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PIWIL1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.349); called by muse, mutect2
- PKHD1L1 | c.5209G>T p.G1737* | Nonsense Mutation (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- PKP4 | c.774del p.S259Vfs*58 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | called by mutect2, pindel, varscan2
- POTEE | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PRAMEF20 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRELP | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- PRG2 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2
- PRKD1 | c.1393-2A>T p.X465_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- PRPF40A | c.2926G>T p.E976* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- PSG2 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 66/615 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- PTPRB | c.4385T>A p.V1462E | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2
- PTPRZ1 | c.4952G>T p.C1651F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAB3GAP1 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAG1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RGL1 | c.1415C>T p.P472L (on ENST00000360851 / NM_001297672.2; = p.P507L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RHBDD1 | c.746del p.G249Afs*20 | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.980del p.G327Efs*3 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- RIT2 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- RPH3A | c.650-1G>T p.X217_splice (on ENST00000389385 / NM_001143854.2; = p.X213_splice on NM_014954.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 47/189 reads (25%) | called by muse, mutect2, varscan2
- RYR2 | c.4142C>A p.P1381H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SCG2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN4A | c.3291G>C p.W1097C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA5A | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- SEMA5B | c.1265dup p.N422Kfs*9 | Frame Shift Ins (INS) | VAF 18/126 reads (14%) | called by mutect2, pindel, varscan2
- SEMA6D | c.965+1G>T p.X322_splice | Splice Site (SNP) | VAF 38/192 reads (20%) | called by muse, mutect2, varscan2
- SERPINB7 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- SETBP1 | c.3039G>T p.L1013F | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.332); called by muse, mutect2
- SETBP1 | c.3967G>T p.E1323* | Nonsense Mutation (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- SIMC1 | c.368G>T p.G123V (on ENST00000443967 / NM_001308196.1; = p.G142V on NM_001308195.2) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- SIX2 | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SLC10A2 | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC18A2 | c.1070+2T>A p.X357_splice | Splice Site (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2, varscan2
- SLC25A37 | c.644A>T p.H215L | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC7A1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A2 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2
- SLCO1B3 | c.1033A>T p.T345S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SLCO6A1 | c.1021+1G>T p.X341_splice | Splice Site (SNP) | VAF 37/195 reads (19%) | called by muse, mutect2, varscan2
- SMTNL2 | c.1186G>T p.D396Y (on ENST00000389313 / NM_001114974.2; = p.D252Y on NM_198501.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SNX13 | c.2797C>T p.H933Y | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SNX14 | c.1097G>A p.C366Y (on ENST00000314673 / NM_001350535.1; = p.C322Y on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- SP110 | c.1651A>T p.T551S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SPAG17 | c.4105A>T p.K1369* | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- SPESP1 | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPG11 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- STMN4 | c.136G>T p.V46F (on ENST00000265770 / NM_001283054.2; = p.V73F on NM_030795.4) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- STON2 | c.2385G>T p.W795C (on ENST00000649389 / NM_001366849.2; = p.W738C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STON2 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2
- STS | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5L | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.979); called by muse, mutect2
- SUGP1 | c.879G>C p.Q293H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SULF1 | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TACC2 | c.6083A>G p.K2028R (on ENST00000334433; = p.K106R on NM_006997.4) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D32 | c.2687A>T p.N896I | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2
- TENM1 | c.4943G>T p.G1648V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TET1 | c.5303A>G p.H1768R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TET3 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- TEX15 | c.4736C>A p.P1579H (on ENST00000256246; = p.P1962H on NM_001350162.2) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFPI2 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TK2 | c.401A>T p.Y134F (on ENST00000299697; = p.Y190F on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLN2 | c.6102del p.V2035Cfs*47 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- TMEM39B | c.519G>T p.W173C | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2
- TP53BP1 | c.4619T>A p.L1540Q | Missense Mutation (SNP) | VAF 86/549 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TP53I3 | c.284A>C p.Q95P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TRAK1 | c.481-2A>T p.X161_splice (on ENST00000327628 / NM_001349247.2; = p.X103_splice on NM_014965.5) | Splice Site (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- TRIO | c.8708T>A p.V2903D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRMT1L | c.2072A>G p.Y691C | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- TTK | c.1729A>T p.K577* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.51744T>A p.D17248E (on ENST00000591111; = p.D9824E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/85 reads (9%) | PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTN | c.38895G>C p.Q12965H (on ENST00000591111; = p.Q5541H on NM_003319.4) | Missense Mutation (SNP) | VAF 4/61 reads (7%) | PolyPhen possibly damaging (0.769); called by muse, mutect2
- TUBB2A | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.403); called by mutect2, varscan2
- TUBGCP6 | c.5453A>T p.D1818V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- UBXN4 | c.1063A>T p.N355Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- UCP1 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- URB2 | c.2005C>A p.L669I | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- USP13 | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- UTP23 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- VRK3 | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WASHC5 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- WDR75 | c.1020G>C p.L340F | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WNT9B | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZBTB18 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZC3H6 | c.1576G>C p.V526L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIC4 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ZNF317 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- ZNF331 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
- ZNF559-ZNF177 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF585B | c.1972G>T p.G658* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- ZNF658 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZSWIM2 | c.1233A>C p.R411S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZZZ3 | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- ABCA13 | c.11808G>A p.L3936= | Silent (SNP) | VAF 33/427 reads (8%) | called by muse, mutect2
- ABCA13 | c.12984A>T p.P4328= | Silent (SNP) | VAF 60/103 reads (58%) | called by muse, mutect2, varscan2
- ADCY2 | c.2559C>A p.R853= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV57859407; called by muse, mutect2, varscan2
- AGAP1 | c.915G>A p.T305= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs982745709, COSV58339846; called by muse, mutect2, varscan2
- AKAP13 | c.369A>T p.G123= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- ALK | c.1056C>T p.H352= | Silent (SNP) | VAF 33/222 reads (15%) | catalogued as rs774038845; called by muse, varscan2
- ANK2 | c.11811C>A p.S3937= | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2
- APOB | c.9810C>T p.F3270= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs138010392; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOB | c.7443G>T p.L2481= | Silent (SNP) | VAF 42/238 reads (18%) | called by muse, varscan2
- ARCN1 | c.429G>T p.V143= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- ASRGL1 | c.273A>G p.A91= | Silent (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- ASTN2 | c.930C>A p.R310= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as COSV57785126; called by muse, mutect2, varscan2
- ATRN | c.1452G>A p.K484= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as COSV99497063; called by muse, mutect2, varscan2
- B4GALT4 | c.774C>T p.G258= | Silent (SNP) | VAF 37/191 reads (19%) | catalogued as rs183964259; called by muse, mutect2, varscan2
- BCL2 | c.396G>T p.T132= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs748305332; called by muse, mutect2, varscan2
- BMPER | c.585G>A p.R195= | Silent (SNP) | VAF 77/629 reads (12%) | called by muse, mutect2, varscan2
- C14orf39 | c.1626A>T p.S542= | Silent (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2
- CA3 | c.477C>T p.F159= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53410024; called by muse, mutect2
- CAMTA1 | c.3462G>T p.R1154= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- CCDC40 | c.2757G>A p.E919= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV66473806; called by muse, mutect2, varscan2
- CD2 | c.1026A>G p.A342= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- CHRM2 | c.513G>T p.V171= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as rs1350147413; called by muse, mutect2, varscan2
- CNGA3 | c.435C>T p.N145= | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- CNTN1 | c.342T>C p.C114= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as rs1555180947; ClinVar: likely benign; called by muse, mutect2
- COL15A1 | c.2025C>A p.P675= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs770786334; called by muse, mutect2, varscan2
- COL19A1 | c.3387C>A p.L1129= | Silent (SNP) | VAF 36/244 reads (15%) | catalogued as COSV100506192; called by muse, mutect2, varscan2
- COPS8 | c.507A>T p.A169= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- DMRT3 | c.675G>A p.A225= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1395808284, COSV99506069; called by muse, mutect2, varscan2
- DNAH1 | c.4107G>T p.L1369= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- DNAH7 | c.3708G>T p.L1236= | Silent (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- DOCK10 | c.6126G>A p.E2042= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs373665902; called by muse, mutect2, varscan2
- EID3 | c.444T>G p.L148= | Silent (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- EPHA1 | c.210A>T p.P70= | Silent (SNP) | VAF 41/225 reads (18%) | called by muse, mutect2, varscan2
- ERICH3 | c.489A>G p.P163= | Silent (SNP) | VAF 92/542 reads (17%) | catalogued as rs776509957; called by muse, mutect2, varscan2
- ESRP1 | c.996G>T p.G332= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs1239872052, COSV64412829; called by muse, varscan2
- FAT3 | c.4869C>A p.I1623= | Silent (SNP) | VAF 15/219 reads (7%) | called by muse, mutect2
- FBN2 | c.5604C>A p.I1868= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs1225703431; called by muse, mutect2, varscan2
- FOXN4 | c.960G>T p.P320= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs761386254, COSV100142098, COSV54498510; called by muse, mutect2
- FSCB | c.726T>A p.V242= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- GABRG3 | c.321T>A p.L107= | Silent (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
- GABRR2 | c.768G>T p.T256= | Silent (SNP) | VAF 6/63 reads (10%) | called by mutect2, varscan2
- GBX2 | c.858C>A p.L286= | Silent (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- GLP2R | c.102C>A p.T34= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1908G>T p.L636= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- HCRTR2 | c.1023T>A p.T341= | Silent (SNP) | VAF 36/199 reads (18%) | called by muse, mutect2, varscan2
- HEY2 | c.789C>A p.T263= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs1242037391, COSV64239525; called by muse, mutect2, varscan2
- HOXD10 | c.150C>A p.T50= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99982771; called by muse, mutect2, varscan2
- HTR1A | c.1149C>G p.A383= | Silent (SNP) | VAF 54/341 reads (16%) | called by muse, mutect2, varscan2
- IGF2BP3 | c.516G>T p.R172= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- IGHV3-35 | c.88T>C p.L30= | Silent (SNP) | VAF 54/680 reads (8%) | called by muse, mutect2
- ITGAD | c.2088T>A p.T696= | Silent (SNP) | VAF 55/388 reads (14%) | called by muse, mutect2, varscan2
- KALRN | c.8905C>A p.R2969= (on ENST00000360013 / NM_001024660.4; = p.R1272= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- KIF2B | c.669C>T p.L223= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV52132836; called by muse, mutect2, varscan2
- KIRREL2 | c.2040G>T p.G680= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- KLHL24 | c.1620T>A p.S540= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- LAX1 | c.147C>A p.L49= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- LGALS14 | c.39C>A p.S13= | Silent (SNP) | VAF 58/287 reads (20%) | called by muse, mutect2, varscan2
- LGR5 | c.318C>A p.P106= | Silent (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- LILRA1 | c.528G>T p.G176= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, varscan2
- LRP1 | c.1617G>T p.R539= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs546104565; called by muse, mutect2, varscan2
- MAB21L3 | c.240C>A p.A80= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1458035578, COSV101046450; called by muse, mutect2, varscan2
- MARK4 | c.1188A>T p.G396= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2
- MC3R | c.489C>T p.T163= | Silent (SNP) | VAF 34/221 reads (15%) | called by muse, mutect2, varscan2
- MERTK | c.2007A>T p.V669= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- MFAP3L | c.627C>T p.P209= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- MROH9 | c.1674C>A p.L558= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs770393911, COSV63010851; called by muse, mutect2, varscan2
- MYH7B | c.480C>T p.L160= | Silent (SNP) | VAF 35/274 reads (13%) | called by muse, mutect2, varscan2
- NAP1L3 | c.738T>A p.P246= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- NHP2 | c.189G>T p.G63= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2, varscan2
- NID1 | c.2952C>T p.A984= | Silent (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- NLRP7 | c.723C>T p.I241= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- NPAP1 | c.516G>A p.E172= | Silent (SNP) | VAF 18/85 reads (21%) | called by muse, varscan2
- NUTM1 | c.1635T>C p.D545= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- OR10Q1 | c.399G>T p.P133= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV57469977; called by muse, mutect2, varscan2
- OR14K1 | c.366T>A p.A122= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- OR4C46 | c.27G>A p.E9= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs778036689; called by muse, mutect2, varscan2
- OR4K14 | c.111C>T p.A37= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- PCDHA11 | c.972G>A p.K324= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1998G>A p.L666= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- PCDHB14 | c.2112G>T p.S704= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs782563810; called by muse, mutect2, varscan2
- PDE5A | c.705G>T p.A235= | Silent (SNP) | VAF 29/201 reads (14%) | called by muse, mutect2, varscan2
- PLCB2 | c.1089G>T p.G363= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- PMVK | c.189G>T p.L63= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- PRX | c.4173G>T p.R1391= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- PSKH2 | c.870C>T p.S290= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- PTPRT | c.1668G>C p.L556= | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- RP1L1 | c.4062G>A p.A1354= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs375108865; ClinVar: benign; called by muse, varscan2
- RYR3 | c.3594C>T p.I1198= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1032258547; ClinVar: likely benign; called by muse, mutect2
- SCYL3 | c.1926A>C p.S642= (on ENST00000367770; = p.S588= on NM_020423.7) | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, varscan2
- SLAMF1 | c.456C>A p.T152= | Silent (SNP) | VAF 23/227 reads (10%) | called by muse, mutect2, varscan2
- SLC1A3 | c.993C>A p.I331= | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as COSV54315283; called by muse, mutect2, varscan2
- SLC1A6 | c.843C>A p.V281= | Silent (SNP) | VAF 26/250 reads (10%) | called by muse, mutect2, varscan2
- SMAD4 | c.876G>T p.P292= | Silent (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- SMYD1 | c.1472G>A p.*491= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- SNRPN | c.393C>A p.V131= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100578259; called by muse, mutect2
- SNTG1 | c.1506T>A p.S502= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- SPTA1 | c.3231T>A p.R1077= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, varscan2
- ST18 | c.792A>G p.A264= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- STAT1 | c.1014G>C p.G338= | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- TBX6 | c.1236C>G p.L412= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- TGIF2LY | c.402C>T p.H134= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- TIAM1 | c.96C>T p.L32= | Silent (SNP) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- TNC | c.3522C>A p.A1174= | Silent (SNP) | VAF 87/392 reads (22%) | catalogued as rs139061925; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1359G>T p.L453= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- TRPC4 | c.513C>A p.P171= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1080G>T p.A360= (on ENST00000580243 / NM_001308210.2; = p.A315= on NM_005786.6) | Silent (SNP) | VAF 6/66 reads (9%) | called by mutect2, varscan2
- TSPAN2 | c.540C>A p.T180= | Silent (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- TTC27 | c.1770A>G p.L590= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1180856822; called by muse, mutect2, varscan2
- UACA | c.444T>C p.S148= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs1566976158; called by muse, mutect2, varscan2
- UGT2B15 | c.390T>C p.D130= | Silent (SNP) | VAF 16/255 reads (6%) | called by muse, mutect2
- VNN2 | c.814C>T p.L272= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- WBP1L | c.78A>T p.T26= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- YEATS2 | c.18A>T p.R6= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- ZEB1 | c.2745G>A p.K915= | Silent (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2
- ZMIZ1 | c.1029G>T p.G343= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1230332480; called by muse, varscan2
- ZNF226 | c.1737G>T p.L579= | Silent (SNP) | VAF 35/213 reads (16%) | called by muse, mutect2, varscan2
- ZNF260 | c.612G>A p.K204= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- ZNF420 | c.246A>G p.E82= | Silent (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- ZNF502 | c.672A>T p.S224= | Silent (SNP) | VAF 78/269 reads (29%) | called by muse, mutect2, varscan2
- ZNF534 | c.138C>T p.S46= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- ZNF540 | c.780A>T p.R260= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- ZNF568 | c.288G>T p.V96= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, varscan2
- ZNF71 | c.936G>T p.S312= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as rs17851130, COSV100045596; called by muse, mutect2, varscan2
- ZNF772 | c.906C>T p.T302= | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- ANKRD33 | c.665-53G>C | Intron (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100001251; called by muse, mutect2, varscan2
- ANKS1B | c.2420-43G>T | Intron (SNP) | VAF 75/278 reads (27%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-1792C>A | Intron (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- FOLH1B | n.1404G>T | RNA (SNP) | VAF 15/95 reads (16%) | catalogued as rs1190880864; called by muse, mutect2, varscan2
- FOLH1B | n.1405G>T | RNA (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85950C>A | Intron (SNP) | VAF 19/248 reads (8%) | called by muse, mutect2
- MIR890 | n.21G>A | RNA (SNP) | VAF 56/137 reads (41%) | catalogued as rs1012992693; called by muse, mutect2, varscan2
- MORF4 | n.276G>T | RNA (SNP) | VAF 45/253 reads (18%) | called by muse, mutect2, varscan2
- NBPF11 | c.-549+2277G>C | Intron (SNP) | VAF 5/26 reads (19%) | catalogued as rs1279056167; called by muse, varscan2
- PNO1 | chr2:68157570 G>C | 5'Flank (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792065 G>A | 3'Flank (SNP) | VAF 7/38 reads (18%) | catalogued as rs1441848699; called by muse, mutect2, varscan2
- TMEM44 | c.1318-4407G>T | Intron (SNP) | VAF 6/102 reads (6%) | catalogued as COSV56447732; called by muse, mutect2
